Somatic mutation profile of tumor specimen TCGA-EO-A3B0-01A (aliquot TCGA-EO-A3B0-01A-12D-A19Y-09) from TCGA case TCGA-EO-A3B0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 43.7 years (15,954 days).
Specimen TCGA-EO-A3B0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 640efb16-5925-43ac-9304-791237992295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A3B0-10A (Blood Derived Normal), aliquot TCGA-EO-A3B0-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c2f4c89-0504-455b-ab29-baee60621fbe

The open-access MAF lists 11,746 somatic variants for this specimen: 9,390 protein-altering or splice-affecting, 2,057 silent, 299 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,053, Silent 2,057, Nonsense Mutation 1,097, Splice Site 131, Intron 116, RNA 92, Splice Region 57, Frame Shift Ins 30, 5'Flank 26, 3'UTR 26, 5'UTR 23, 3'Flank 16.

Variants (750 of 11,746; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.6709C>T p.R2237* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs768922431, CM130062, COSV57327470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs1568359887, COSV52464695; ClinVar: pathogenic; called by mutect2, varscan2
- ATF6 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761357250, CM156874, COSV63405743; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP8A2 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs1304109530, COSV54935035; ClinVar: likely pathogenic; called by muse, varscan2
- AVPR2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28935496, CM930063, COSV61686589; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs397508296, CM920165, COSV50040595, COSV99140566; ClinVar: pathogenic; called by mutect2, varscan2
- CLN5 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as rs386833971, CM120887, COSV66285061; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- COL11A2 | c.3100C>T p.R1034C (on ENST00000341947 / NM_080680.3; = p.R927C on NM_080679.2) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121912947, CM993117, COSV59497876; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CYP1B1 | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as rs377049098, CM033367; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 36/96 reads (38%) | catalogued as rs398124050, CM040026, COSV58905803; ClinVar: pathogenic; called by muse, varscan2
- DYRK1A | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs780441716, COSV58295398; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs724159953, CM1510739, COSV58292386; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDA | c.180C>A p.C60* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as rs1131692034; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852435, CM920257, COSV64271004; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- F9 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs137852274, CM001674, CM940471, COSV54380607; ClinVar: pathogenic; called by muse, varscan2
- FBN1 | c.8521G>T p.E2841* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as rs587782948, CM118006, COSV57310584, COSV57313168; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- FGF8 | c.346C>T p.R116* (on ENST00000344255 / NM_033164.4; = p.R98* on NM_006119.6) | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as rs137852663, CM082676, CM104200, COSV60143465; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLAD1 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as rs199979286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLG | c.10969C>T p.R3657* | Nonsense Mutation (SNP) | VAF 43/196 reads (22%) | catalogued as rs749083759, COSV64243715; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- KANSL1 | c.1652+1G>A p.X551_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as rs281865470, CS124331, COSV52267422, COSV52272538; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNB1 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs781663444, COSV65570639; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as rs17215500, CM057185, CM992171; ClinVar: pathogenic / benign / uncertain significance; called by muse, mutect2, varscan2
- MAGEL2 | c.2296C>T p.R766* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs1249139977; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAT1A | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs72558181, CM970910, COSV64745225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.294T>A p.Y98* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs763872353, CD117465, COSV51887435; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYF6 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.742); catalogued as rs747205109, COSV57353234; ClinVar: likely pathogenic; called by mutect2, varscan2
- MYL2 | c.52T>C p.F18L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs104894370, CM981331, COSV57406408; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NCF2 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as rs374402066, CM992362; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NDUFS1 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as rs750971390, COSV51907881, COSV99260518; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX12 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 24/39 reads (62%) | catalogued as rs61752103, CM981517, COSV56777816; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PJVK | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs111706634, CM062580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs121908685, CM063030, COSV59267862; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 24/31 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 38/90 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RHO | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.809); catalogued as rs104893779, CM910342, CM930659, COSV99960759; ClinVar: pathogenic; called by mutect2, varscan2
- RPS6KA3 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs122454129, CM991111, COSV65389911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC19A3 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1131691615, CM157656; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50994862; called by muse, mutect2, varscan2
- SMAD4 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV61687696; called by muse, mutect2, varscan2
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 61/151 reads (40%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TAB2 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs1057518422; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- THRB | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918695, CM910363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM216 | c.217C>T p.R73C (on ENST00000515837 / NM_001173990.3; = p.R12C on NM_016499.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779526456, CM121486, COSV100609944, COSV58425974; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 34/56 reads (61%) | catalogued as rs751517725, COSV60036110; ClinVar: pathogenic; called by muse, varscan2
- TRIO | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as rs1057516029, COSV60077909; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs371980049; called by muse, mutect2, varscan2
- A2M | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs753857154, COSV59389120, COSV59390257; called by mutect2, varscan2
- AACS | c.1207A>G p.M403V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs745614910; called by mutect2, varscan2
- AARS1 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs763513667; called by muse, mutect2, varscan2
- AASDH | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV52705491; called by muse, mutect2, varscan2
- ABCA1 | c.6054G>T p.E2018D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs750154460; called by muse, mutect2, varscan2
- ABCA1 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV66065648; called by muse, mutect2
- ABCA1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs777890632, CM109182; called by muse, varscan2
- ABCA10 | c.1963G>T p.E655* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV99287574; called by muse, mutect2, varscan2
- ABCA12 | c.5600G>T p.R1867I (on ENST00000272895 / NM_173076.3; = p.R1549I on NM_015657.3) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV55967642; called by muse, mutect2, varscan2
- ABCA12 | c.2725G>A p.D909N (on ENST00000272895 / NM_173076.3; = p.D591N on NM_015657.3) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as rs767059932, COSV55963360; called by muse, mutect2, varscan2
- ABCA13 | c.6268A>C p.N2090H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.803); catalogued as rs776563718; called by mutect2, varscan2
- ABCA13 | c.11602G>T p.D3868Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs1284467651; called by muse, mutect2, varscan2
- ABCA13 | c.12259G>T p.D4087Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as rs1469185233; called by muse, mutect2, varscan2
- ABCA13 | c.13336G>A p.E4446K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs6583448; called by muse, mutect2, varscan2
- ABCA13 | c.14392G>A p.V4798M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs371163165; called by muse, mutect2, varscan2
- ABCA3 | c.4498C>T p.R1500W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs969485084, COSV57052117; called by muse, mutect2, varscan2
- ABCA4 | c.6136G>T p.E2046* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV64670928; called by muse, mutect2, varscan2
- ABCA5 | c.4843G>T p.E1615* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV52228263; called by muse, mutect2, varscan2
- ABCA5 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.334); catalogued as COSV67017752; called by muse, mutect2, varscan2
- ABCA6 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV104371284, COSV52639818; called by muse, mutect2, varscan2
- ABCA7 | c.680T>G p.V227G | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99565783; called by muse, mutect2, varscan2
- ABCA8 | c.4602C>A p.S1534R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV104393364, COSV52199588; called by muse, mutect2, varscan2
- ABCA8 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs768333090, COSV52197981; called by muse, mutect2, varscan2
- ABCA9 | c.4468C>T p.R1490* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs1234058143, COSV60629637; called by muse, mutect2, varscan2
- ABCA9 | c.3888G>T p.K1296N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV100382762; called by muse, mutect2, varscan2
- ABCA9 | c.3484C>A p.L1162I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs757163962; called by muse, mutect2, varscan2
- ABCA9 | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV104412045; called by muse, mutect2, varscan2
- ABCB4 | c.3304C>A p.L1102I (on ENST00000265723 / NM_018849.3; = p.L1095I on NM_000443.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.168); catalogued as rs780850288; called by muse, mutect2
- ABCB4 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs998072340; called by muse, mutect2, varscan2
- ABCB5 | c.2626-1G>A p.X876_splice (on ENST00000404938 / NM_001163941.2; = p.X431_splice on NM_178559.6) | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as rs147879229, COSV51717353; called by muse, varscan2
- ABCB5 | c.2689G>A p.E897K (on ENST00000404938 / NM_001163941.2; = p.E452K on NM_178559.6) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.18); catalogued as rs747891566; called by muse, varscan2
- ABCC10 | c.1726G>A p.D576N (on ENST00000372530 / NM_001198934.2; = p.D533N on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs762674596; called by muse, mutect2, varscan2
- ABCC12 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745699306, COSV60916223; called by muse, mutect2, varscan2
- ABCC2 | c.4250C>A p.S1417Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs749883731; called by muse, mutect2, varscan2
- ABCC8 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs749857214; called by muse, mutect2, varscan2
- ABCD4 | c.1392C>A p.F464L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV53991415; called by muse, varscan2
- ABCG2 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1177738977, COSV52944962; called by muse, varscan2
- ABCG2 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as rs201034377, COSV52948355; called by muse, mutect2, varscan2
- ABHD1 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as COSV99574274; called by muse, mutect2, varscan2
- ABHD1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs371626040; called by muse, mutect2, varscan2
- ABI2 | c.1059G>T p.M353I (on ENST00000295851 / NM_001375719.1; = p.M286I on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.832); catalogued as COSV53689741; called by muse, mutect2, varscan2
- ABI3BP | c.2389C>T p.R797* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as rs751897262, COSV52532905; called by muse, mutect2, varscan2
- ABI3BP | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV99428460; called by muse, varscan2
- AC013477.1 | c.2482C>T p.R828* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as rs777485668; called by muse, mutect2, varscan2
- AC093827.5 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV55744624; called by muse, mutect2, varscan2
- AC109583.1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs778911563; called by mutect2, varscan2
- ACADS | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs756016434, COSV54368224; called by muse, mutect2, varscan2
- ACAN | c.5155G>T p.A1719S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.661); catalogued as COSV61355640; called by muse, mutect2, varscan2
- ACAN | c.6845C>T p.S2282F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs752044557; called by muse, mutect2, varscan2
- ACBD7 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs371874832; called by muse, mutect2, varscan2
- ACCSL | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs779207509, COSV66583035; called by muse, mutect2, varscan2
- ACE | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs148144906, COSV52006719; called by muse, mutect2, varscan2
- ACSBG1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV51911410; called by muse, varscan2
- ACSF2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781188170, COSV51971814; called by muse, mutect2, varscan2
- ACSF2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571347004, COSV51973316; called by muse, mutect2, varscan2
- ACSL1 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV55663688; called by mutect2, varscan2
- ACSL4 | c.2015G>A p.R672Q (on ENST00000340800 / NM_022977.2; = p.R631Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); catalogued as rs370335449; called by muse, mutect2, varscan2
- ACSM2B | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as rs1471931670; called by muse, varscan2
- ACSM4 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs1412358684, COSV68067591, COSV68067628; called by muse, mutect2, varscan2
- ACSM5 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.717); catalogued as rs1159631710, COSV59371094, COSV59374555; called by muse, mutect2, varscan2
- ACTL6B | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs768097253; called by muse, mutect2, varscan2
- ACTN4 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs763051766, COSV53147827; called by muse, mutect2, varscan2
- ACTR3B | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1483601533; called by muse, mutect2, varscan2
- ACTR3B | c.337-1G>A p.X113_splice | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99754372; called by muse, mutect2, varscan2
- ACTRT1 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100947485, COSV100947702; called by muse, mutect2, varscan2
- ACVR1C | c.1297A>C p.K433Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs992621475; called by muse, mutect2, varscan2
- ACVRL1 | c.1275C>A p.F425L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as CM040666; called by muse, mutect2, varscan2
- ADAD1 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV56648189; called by muse, mutect2, varscan2
- ADAM10 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs779647116, COSV53052019; called by mutect2, varscan2
- ADAM17 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs369159078; called by muse, mutect2, varscan2
- ADAM23 | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs372500763; called by muse, mutect2, varscan2
- ADAM8 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs759368536, COSV101291604; called by muse, mutect2, varscan2
- ADAM9 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV101122256; called by muse, mutect2, varscan2
- ADAMTS12 | c.4435A>G p.N1479D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1455540117; called by muse, mutect2, varscan2
- ADAMTS16 | c.2156G>A p.R719K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1360875546; called by muse, mutect2, varscan2
- ADAMTS17 | c.2032G>A p.G678S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.53); catalogued as rs201492720, COSV51473640, COSV51482658; called by muse, mutect2, varscan2
- ADAMTS18 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1355815263, COSV51402328; called by muse, mutect2, varscan2
- ADAMTS7 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs906389735, COSV101183029; called by muse, mutect2
- ADAMTS9 | c.3944G>A p.R1315H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs771279906; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65899174; called by muse, mutect2, varscan2
- ADCY1 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52032751; called by muse, mutect2, varscan2
- ADCY6 | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs1266593450; called by muse, mutect2, varscan2
- ADCY7 | c.965G>T p.R322L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202891173, COSV54264517; called by muse, mutect2, varscan2
- ADCY8 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs756739239; called by muse, mutect2, varscan2
- ADCY9 | c.2962C>T p.L988F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53577066; called by mutect2, varscan2
- ADCY9 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV53574790; called by muse, mutect2, varscan2
- ADCYAP1 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV99327492; called by muse, varscan2
- ADD2 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV52464350; called by muse, mutect2, varscan2
- ADGRA2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs199845696; called by muse, varscan2
- ADGRA2 | c.1419T>G p.F473L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.437); catalogued as COSV104408543; called by muse, varscan2
- ADGRB3 | c.1268G>T p.R423I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101001261; called by muse, mutect2, varscan2
- ADGRB3 | c.1833C>A p.F611L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.437); catalogued as COSV65383768; called by mutect2, varscan2
- ADGRB3 | c.3527C>T p.S1176L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs142863825, COSV53234039; called by muse, mutect2, varscan2
- ADGRD1 | c.311-2A>G p.X104_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as rs762138760; called by muse, mutect2, varscan2
- ADGRE5 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV54414709; called by muse, mutect2, varscan2
- ADGRF1 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs368135595, COSV99347518; called by muse, mutect2, varscan2
- ADGRF2 | c.1763A>G p.Y588C (on ENST00000296862 / NM_001368115.2; = p.Y520C on NM_153839.7) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780514523; called by muse, mutect2, varscan2
- ADGRF4 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs772794418, COSV51949756; called by muse, mutect2, varscan2
- ADGRF4 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as rs145448448; called by muse, mutect2, varscan2
- ADGRF5 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs139730967; called by muse, mutect2, varscan2
- ADGRG4 | c.3921T>G p.I1307M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV54952867; called by muse, mutect2, varscan2
- ADGRG4 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV54950689; called by muse, varscan2
- ADGRG4 | c.8468C>A p.S2823Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54953030, COSV99796578; called by muse, mutect2, varscan2
- ADGRG5 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs370454204; called by muse, mutect2, varscan2
- ADGRG6 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs748864894; called by muse, mutect2, varscan2
- ADGRG6 | c.3255C>A p.F1085L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.34); catalogued as COSV99747042; called by muse, mutect2, varscan2
- ADGRG7 | c.1677G>T p.M559I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV99840828; called by muse, mutect2, varscan2
- ADGRL3 | c.396A>C p.K132N (on ENST00000506720 / NM_001322402.2; = p.K64N on NM_015236.6) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV72269705; called by muse, mutect2, varscan2
- ADGRV1 | c.5212G>T p.E1738* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV67996969; called by muse, mutect2, varscan2
- ADGRV1 | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs755180090; ClinVar: uncertain significance; called by mutect2, varscan2
- ADGRV1 | c.10517G>A p.R3506K | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs764955627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADH1C | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV72463453; called by muse, mutect2, varscan2
- ADH6 | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV52955169; called by muse, mutect2, varscan2
- ADHFE1 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as rs368995778; called by muse, mutect2, varscan2
- ADHFE1 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.866); catalogued as rs747308128; called by muse, mutect2, varscan2
- ADK | c.67G>T p.E23* (on ENST00000286621; = p.E6* on NM_001123.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as rs1024367383; called by muse, mutect2, varscan2
- ADPRHL1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs746264712, COSV100733323; called by muse, varscan2
- ADPRS | c.770C>A p.S257* | Nonsense Mutation (SNP) | VAF 48/107 reads (45%) | catalogued as COSV52882169; called by muse, mutect2, varscan2
- ADRA1B | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100140509; called by muse, mutect2, varscan2
- ADRA2B | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69787168; called by muse, mutect2, varscan2
- ADSS1 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as rs1175271315; called by muse, mutect2, varscan2
- ADSS1 | c.741dup p.K248Qfs*16 | Frame Shift Ins (INS) | VAF 24/61 reads (39%) | catalogued as rs769542442; called by mutect2, varscan2
- ADSS1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760473533; called by muse, mutect2, varscan2
- AFAP1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | catalogued as rs749129062, COSV61794643; called by mutect2, varscan2
- AFAP1L2 | c.403A>T p.N135Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs1438046057; called by muse, mutect2, varscan2
- AFF2 | c.1839G>T p.K613N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53981239; called by muse, mutect2, varscan2
- AFF2 | c.2883C>A p.F961L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.473); catalogued as COSV99665297; called by muse, varscan2
- AFP | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV56924084; called by muse, mutect2, varscan2
- AFTPH | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs1179899621, COSV53217911; called by muse, varscan2
- AGAP1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs750448988, COSV58329822; called by muse, mutect2, varscan2
- AGAP2 | c.2507A>C p.K836T (on ENST00000547588 / NM_001122772.2; = p.K500T on NM_014770.4) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV57727624; called by muse, mutect2, varscan2
- AGAP2 | c.2091G>T p.K697N (on ENST00000547588 / NM_001122772.2; = p.K361N on NM_014770.4) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57731582; called by muse, mutect2, varscan2
- AGBL2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750588811, COSV54091149; called by muse, mutect2, varscan2
- AGBL2 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781464867; called by muse, mutect2, varscan2
- AGMAT | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs1343767993; called by muse, mutect2, varscan2
- AGMO | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV61120874; called by muse, mutect2, varscan2
- AGO2 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1434061112; called by muse, mutect2, varscan2
- AGO2 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs773613021, COSV99596319; called by muse, mutect2, varscan2
- AGPAT4 | c.1023C>A p.F341L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs763397162; called by muse, mutect2, varscan2
- AGPAT5 | c.885T>G p.F295L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV53447755; called by muse, mutect2, varscan2
- AGPS | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs1372190083, COSV51561302; called by muse, mutect2, varscan2
- AGR2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs375782337; called by muse, mutect2
- AGTPBP1 | c.1553G>T p.R518I (on ENST00000357081 / NM_001330701.2; = p.R478I on NM_015239.2) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV61268456; called by muse, mutect2, varscan2
- AGXT2 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs1554036019, COSV51486089; called by muse, mutect2, varscan2
- AHNAK | c.4180G>A p.G1394S | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as rs767542353, COSV99948487; called by muse, mutect2, varscan2
- AHNAK | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 41/96 reads (43%) | catalogued as rs1291139419; called by muse, mutect2, varscan2
- AHNAK2 | c.16468C>A p.L5490I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as COSV60911036, COSV60924087; called by muse, mutect2
- AHNAK2 | c.14047G>A p.D4683N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs375463111; called by muse, mutect2, varscan2
- AHNAK2 | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV60922388; called by muse, mutect2, varscan2
- AHNAK2 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100318059; called by muse, mutect2, varscan2
- AHRR | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs755562732; called by muse, varscan2
- AHSG | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as rs1167655884; called by muse, mutect2, varscan2
- AK8 | c.333+2T>G p.X111_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as COSV53758841; called by muse, mutect2, varscan2
- AKAP13 | c.6591G>T p.K2197N (on ENST00000394518 / NM_007200.5; = p.K2201N on NM_006738.6) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774250; called by muse, mutect2, varscan2
- AKAP3 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as rs144694533; called by muse, mutect2, varscan2
- AKAP4 | c.1154C>A p.S385Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62074182; called by muse, mutect2, varscan2
- AKAP4 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.817); catalogued as rs782377975, COSV62074933; called by muse, mutect2, varscan2
- AKAP6 | c.4369G>T p.E1457* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs1245302165, COSV99803600; called by muse, mutect2, varscan2
- AKNAD1 | c.2380-1G>T p.X794_splice | Splice Site (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100892497; called by muse, mutect2, varscan2
- AKNAD1 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776063336, COSV62199001; called by muse, mutect2, varscan2
- AKR1B15 | c.996C>A p.F332L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1562953724; called by muse, mutect2, varscan2
- AKR1C4 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV54122982, COSV99578579; called by muse, mutect2, varscan2
- AKR1E2 | c.854T>C p.L285S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781298195; called by mutect2, varscan2
- AKT1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1200003171, COSV62574185; called by muse, mutect2
- AL592490.1 | c.2191C>T p.L731F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.306); catalogued as COSV69426556; called by muse, mutect2, varscan2
- AL645922.1 | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100190723; called by muse, mutect2, varscan2
- ALDH18A1 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.848); catalogued as rs766264810, CM157501, COSV64663711; called by mutect2, varscan2
- ALDH18A1 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs113678237; called by muse, mutect2, varscan2
- ALDH1L1 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs748879861, COSV56411012, COSV56416487; called by muse, mutect2, varscan2
- ALDH4A1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1210956458; called by muse, mutect2, varscan2
- ALG11 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs754572359, COSV101584404; called by muse, mutect2, varscan2
- ALG5 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs994296033, COSV104382637; called by muse, mutect2, varscan2
- ALOXE3 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59078305; called by muse, mutect2, varscan2
- ALPK1 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99452952; called by muse, mutect2, varscan2
- ALPK1 | c.2991G>T p.E997D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.321); catalogued as COSV99455538; called by muse, mutect2, varscan2
- ALPK2 | c.1061T>C p.V354A | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV64489945; called by muse, mutect2, varscan2
- ALS2 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs769268310, COSV51891687; called by mutect2, varscan2
- AMBRA1 | c.2837C>T p.S946L (on ENST00000458649 / NM_001367468.1; = p.S856L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs932975059, COSV54062015; called by muse, mutect2, varscan2
- AMELX | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61630685; called by muse, mutect2, varscan2
- AMER2 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV100766376; called by muse, mutect2, varscan2
- AMER3 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58466153; called by muse, mutect2, varscan2
- AMN | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs199835580; called by muse, mutect2, varscan2
- AMOTL1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs745769559; called by muse, mutect2, varscan2
- AMPD1 | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1354451905, COSV62415508; called by muse, mutect2, varscan2
- AMPD3 | c.1854G>T p.L618F (on ENST00000396553 / NM_001025389.2; = p.L627F on NM_000480.3) | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs756852081; called by muse, varscan2
- AMPH | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as COSV57751315; called by muse, mutect2, varscan2
- ANGPT4 | c.835+1G>A p.X279_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as COSV67922673; called by muse, mutect2, varscan2
- ANK2 | c.3827T>G p.I1276S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100004573; called by muse, mutect2, varscan2
- ANK2 | c.6298C>A p.P2100T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.023); catalogued as rs577303232; called by muse, mutect2, varscan2
- ANK2 | c.10223G>A p.R3408Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs759274800, COSV52153095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2
- ANKEF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs774211930, COSV65691928; called by mutect2, varscan2
- ANKEF1 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs112122636; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51845510; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2843C>A p.S948Y | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); catalogued as rs755308583, COSV51844925; called by muse, varscan2
- ANKIB1 | c.2329C>T p.R777* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV56061948; called by muse, mutect2, varscan2
- ANKIB1 | c.2414G>A p.S805N | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1238241498; called by muse, mutect2, varscan2
- ANKK1 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58270663; called by muse, mutect2, varscan2
- ANKK1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1295055275; called by muse, mutect2, varscan2
- ANKK1 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs748104280; called by mutect2, varscan2
- ANKMY1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs766315371; called by muse, mutect2, varscan2
- ANKRD13B | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs765230316, COSV101198839; called by muse, mutect2, varscan2
- ANKRD13C | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV52032769; called by muse, mutect2, varscan2
- ANKRD13C | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99257143; called by muse, mutect2
- ANKRD17 | c.6164T>C p.V2055A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1222123648; called by muse, mutect2, varscan2
- ANKRD24 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs758310661, COSV53668981; called by muse, mutect2, varscan2
- ANKRD24 | c.1893G>T p.E631D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99518074; called by muse, mutect2, varscan2
- ANKRD30A | c.3682G>T p.D1228Y (on ENST00000611781; = p.D1172Y on NM_052997.2) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746157849; called by muse, mutect2, varscan2
- ANKRD44 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56555888; called by muse, mutect2, varscan2
- ANKRD50 | c.3446C>T p.S1149L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1225400170, COSV72385307; called by muse, mutect2, varscan2
- ANKRD52 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1267149410; called by muse, mutect2, varscan2
- ANKRD52 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99921807; called by muse, mutect2, varscan2
- ANKS3 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs550173236; called by muse, mutect2, varscan2
- ANO2 | c.2817G>T p.K939N (on ENST00000356134 / NM_001278597.3; = p.K943N on NM_001278596.3) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as COSV59028642; called by muse, varscan2
- ANO3 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748775110; called by muse, mutect2, varscan2
- ANO4 | c.311G>T p.R104I (on ENST00000392977 / NM_001286615.2; = p.R69I on NM_178826.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54591769; called by mutect2, varscan2
- ANO4 | c.1874A>G p.Y625C (on ENST00000392977 / NM_001286615.2; = p.Y590C on NM_178826.4) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs748862613, COSV100153446, COSV54600154; called by muse, varscan2
- ANO6 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs754292177; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2, varscan2
- ANP32D | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV56980427; called by muse, mutect2, varscan2
- ANXA3 | c.315C>T p.G105= | Splice Region (SNP) | VAF 11/27 reads (41%) | catalogued as rs746083634, COSV53715832; called by muse, mutect2, varscan2
- ANXA8 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1234169612; called by muse, mutect2, varscan2
- AOC1 | c.1795T>C p.S599P | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs1444272809; called by muse, mutect2, varscan2
- AOC3 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as rs139601722; called by muse, mutect2, varscan2
- AOPEP | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 35/70 reads (50%) | catalogued as rs201770998; called by muse, mutect2, varscan2
- AOPEP | c.2180G>A p.R727Q (on ENST00000375315 / NM_001193329.1; = p.R628Q on NM_032823.5) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs963224133, COSV52987575; called by muse, mutect2, varscan2
- AOX1 | c.1705-1G>T p.X569_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV101021833; called by muse, mutect2, varscan2
- AOX1 | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs767970704, COSV65982275; called by muse, mutect2, varscan2
- AP4E1 | c.2233A>G p.I745V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1285189351; called by muse, mutect2, varscan2
- AP4E1 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as COSV55918264; called by muse, mutect2, varscan2
- APBA1 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756578388, COSV99595789; called by muse, mutect2, varscan2
- APC | c.2138C>T p.S713L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM910032, COSV57327842, COSV99971722; called by muse, mutect2, varscan2
- APC | c.3927A>C p.E1309D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.262); catalogued as CD920817, HX080001; called by muse, mutect2, varscan2
- APCDD1L | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV64487156; called by muse, mutect2, varscan2
- APCDD1L | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1273763703, COSV64487943; called by muse, mutect2, varscan2
- APH1A | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52529934; called by muse, mutect2, varscan2
- API5 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as rs372123869; called by muse, mutect2, varscan2
- APOB | c.13034T>G p.F4345C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.855); catalogued as COSV99267675; called by muse, mutect2, varscan2
- APOB | c.9849C>A p.F3283L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51936132; called by muse, mutect2, varscan2
- APOB | c.9306C>A p.F3102L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.908); catalogued as COSV51922023; called by muse, mutect2, varscan2
- APOB | c.1964T>C p.I655T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV51938792; called by muse, mutect2, varscan2
- APOBEC4 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756203206, COSV58017650; called by muse, mutect2, varscan2
- APOH | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV52773206, COSV52775103; called by muse, mutect2, varscan2
- APOL6 | c.118A>C p.K40Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.393); catalogued as rs1175010135; called by muse, mutect2
- APPL1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs748607720, COSV55702014; called by muse, mutect2, varscan2
- AQP9 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV54967982; called by muse, mutect2, varscan2
- AQR | c.3052C>T p.R1018* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV50030477; called by muse, mutect2, varscan2
- ARFGEF1 | c.5321G>A p.R1774Q | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232838320; called by muse, mutect2, varscan2
- ARHGAP17 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757526992, COSV51509775; called by muse, mutect2, varscan2
- ARHGAP18 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs758236154; called by muse, varscan2
- ARHGAP20 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs776868682; called by muse, mutect2, varscan2
- ARHGAP21 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57605752; called by muse, mutect2, varscan2
- ARHGAP25 | c.1250C>T p.A417V (on ENST00000409202 / NM_001007231.3; = p.A409V on NM_014882.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1243471707; called by muse, mutect2, varscan2
- ARHGAP28 | c.890C>T p.T297M (on ENST00000383472 / NM_001366230.1; = p.T138M on NM_001010000.3) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs765768815; called by muse, varscan2
- ARHGAP29 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs41311170, COSV53110573; called by muse, mutect2, varscan2
- ARHGAP32 | c.4240C>T p.P1414S (on ENST00000310343 / NM_001378025.1; = p.P1065S on NM_014715.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as rs1467391505; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP36 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370750175, COSV52271370; called by muse, varscan2
- ARHGAP45 | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV57431852; called by muse, mutect2, varscan2
- ARHGAP5 | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV61539363; called by muse, mutect2, varscan2
- ARHGAP5 | c.3706G>T p.E1236* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99067940; called by muse, mutect2, varscan2
- ARHGEF12 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV63102487; called by muse, mutect2, varscan2
- ARHGEF12 | c.3064C>A p.H1022N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1195857306; called by muse, mutect2, varscan2
- ARHGEF12 | c.4092G>T p.E1364D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.97); catalogued as COSV100755268; called by muse, mutect2, varscan2
- ARHGEF16 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65682048; called by muse, mutect2, varscan2
- ARHGEF2 | c.1031G>A p.R344H (on ENST00000361247 / NM_001162383.2; = p.R316H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.875); catalogued as rs772247274, COSV58110138; called by muse, varscan2
- ARHGEF4 | c.1538A>G p.Q513R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV58131285; called by muse, mutect2, varscan2
- ARHGEF40 | c.4528C>T p.R1510* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as rs772521058, COSV100070617; called by mutect2, varscan2
- ARHGEF6 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs970851888, COSV51695337; called by muse, mutect2, varscan2
- ARID2 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as rs938510522, COSV57616191; called by muse, mutect2
- ARID4A | c.2174A>C p.E725A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV99049426; called by muse, varscan2
- ARIH2 | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as rs1237927374; called by muse, mutect2, varscan2
- ARL11 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs566163670, COSV56290607; called by muse, mutect2, varscan2
- ARL13B | c.610G>T p.E204* (on ENST00000394222 / NM_001174150.2; = p.E97* on NM_144996.4) | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100115243; called by muse, mutect2, varscan2
- ARMC12 | c.258G>T p.K86N (on ENST00000373866 / NM_001286574.2; = p.K113N on NM_145028.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99849382; called by muse, mutect2, varscan2
- ARMC3 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as rs1269246184; called by muse, varscan2
- ARMC4 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV100536620, COSV59458741; called by muse, mutect2, varscan2
- ARMCX2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs781783235, COSV57529674; called by muse, mutect2, varscan2
- ARMH4 | c.1760G>A p.R587K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV50773944; called by muse, mutect2, varscan2
- ARMS2 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV101600751; called by muse, mutect2, varscan2
- ARNT | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV104416818; called by muse, mutect2, varscan2
- ARNT2 | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV57585925; called by muse, mutect2, varscan2
- ARPC2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs1433485062, COSV55283528; called by muse, mutect2, varscan2
- ARSD | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs750661580, COSV54201298; called by muse, mutect2, varscan2
- ARSH | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs907740496, COSV66963179; called by muse, mutect2, varscan2
- ARSI | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs149948064; called by muse, mutect2, varscan2
- ARV1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV59617021; called by muse, mutect2, varscan2
- ASAH2 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV61484009; called by muse, mutect2, varscan2
- ASB11 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV60354331; called by muse, varscan2
- ASB15 | c.1443C>A p.F481L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99306237; called by muse, mutect2, varscan2
- ASB16 | c.567G>A p.L189= | Splice Region (SNP) | VAF 4/19 reads (21%) | catalogued as COSV53235057; called by muse, mutect2, varscan2
- ASB7 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.812); catalogued as COSV100235122; called by muse, mutect2, varscan2
- ASB9 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs1367472178; called by muse, mutect2
- ASCC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752951712, COSV100225437, COSV61226544; called by muse, mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASCL1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs754672998; called by muse, mutect2, varscan2
- ASH1L | c.4960G>A p.E1654K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.695); catalogued as rs755635578; called by muse, mutect2, varscan2
- ASIC4 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs757872748, COSV61730943; called by muse, mutect2, varscan2
- ASPA | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV99559298; called by muse, mutect2, varscan2
- ASPH | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as COSV65244129; called by muse, mutect2, varscan2
- ASPM | c.6686G>T p.R2229I | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV54135319; called by muse, mutect2, varscan2
- ASPM | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs142655430, COSV54127984; called by muse, mutect2, varscan2
- ASPM | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV99660727; called by muse, mutect2, varscan2
- ASTN2 | c.2702G>A p.G901D (on ENST00000313400 / NM_001365069.1; = p.G850D on NM_014010.5) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100526393; called by muse, mutect2, varscan2
- ASXL2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV55468830, COSV55469533; called by muse, mutect2, varscan2
- ASXL3 | c.2797C>T p.R933W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs376307971; called by muse, mutect2, varscan2
- ASXL3 | c.4400G>A p.R1467Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs754700314, COSV52462808; called by muse, mutect2, varscan2
- ASXL3 | c.5109A>C p.Q1703H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV52460893; called by muse, mutect2, varscan2
- ASZ1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV52911190; called by muse, mutect2, varscan2
- ATAD2 | c.2812C>A p.L938I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV54879576; called by muse, mutect2, varscan2
- ATAD2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54881389, COSV54888536; called by muse, mutect2, varscan2
- ATAD5 | c.4403T>G p.I1468S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV58974063; called by muse, mutect2, varscan2
- ATG2B | c.6173G>T p.R2058I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55889456; called by muse, mutect2, varscan2
- ATG2B | c.3643-1G>T p.X1215_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99951979; called by muse, mutect2, varscan2
- ATG2B | c.3575C>T p.A1192V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99952232; called by muse, mutect2, varscan2
- ATG4C | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs1305572848; called by muse, varscan2
- ATG4C | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs757550339; called by muse, mutect2, varscan2
- ATG9B | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1446883497, COSV99874902; called by muse, mutect2, varscan2
- ATM | c.2135C>A p.S712* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as CM149291, COSV53735654; called by muse, mutect2, varscan2
- ATM | c.4255C>A p.L1419I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53761365; called by muse, mutect2
- ATM | c.7199G>T p.R2400I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as rs567457294, COSV53768686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.8983C>A p.L2995I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs142322668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.3223A>C p.I1075L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759238751; called by muse, mutect2, varscan2
- ATP10A | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs201154784; called by muse, mutect2, varscan2
- ATP10A | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs766814441, COSV63516442; called by muse, mutect2, varscan2
- ATP10D | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs750138858, COSV56704068; called by muse, mutect2
- ATP11B | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV60027754; called by muse, mutect2, varscan2
- ATP12A | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54523344; called by muse, mutect2, varscan2
- ATP13A3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs755718276, COSV55462722; called by muse, mutect2, varscan2
- ATP13A4 | c.3277G>T p.E1093* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100710145, COSV100710427; called by muse, mutect2, varscan2
- ATP13A5 | c.2193G>T p.K731N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1167129944, COSV100665273, COSV60867694; called by muse, mutect2, varscan2
- ATP1A3 | c.2068G>A p.E690K (on ENST00000545399 / NM_001256214.2; = p.E677K on NM_152296.5) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868985739; called by muse, mutect2, varscan2
- ATP1B2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); catalogued as rs536546994, COSV51516381; called by muse, mutect2, varscan2
- ATP2A1 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63920520; called by muse, mutect2, varscan2
- ATP2A3 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs771282704; called by muse, varscan2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, varscan2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP2C2 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575721893; called by muse, mutect2, varscan2
- ATP5PD | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as rs377594522, COSV56902613; called by muse, mutect2, varscan2
- ATP6AP1 | c.597C>T p.N199= | Splice Region (SNP) | VAF 11/40 reads (28%) | catalogued as rs782427033; called by muse, mutect2, varscan2
- ATP6V0D1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs777256753, COSV52097335; called by muse, mutect2, varscan2
- ATP7A | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV58444929; called by muse, mutect2, varscan2
- ATP8A2 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as rs777646390, COSV54950188, COSV54971713; called by muse, mutect2, varscan2
- ATP8A2 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200573494, COSV54938064; called by muse, mutect2, varscan2
- ATR | c.2112G>T p.K704N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV63391705; called by muse, mutect2, varscan2
- ATR | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs760248783, COSV63392926; called by muse, mutect2, varscan2
- ATR | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV63385454; called by muse, mutect2, varscan2
- ATRAID | c.433C>A p.H145N (on ENST00000611786; = p.H32N on NM_016085.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.062); catalogued as rs755941611; called by muse, mutect2, varscan2
- ATRIP | c.543C>A p.F181L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as COSV104411059; called by muse, mutect2, varscan2
- ATRNL1 | c.1102T>G p.F368V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV61797880; called by muse, mutect2, varscan2
- ATRNL1 | c.3006G>T p.K1002N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.721); catalogued as COSV100372028, COSV58120915; called by muse, mutect2, varscan2
- ATRNL1 | c.3412G>T p.E1138* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV58095710; called by muse, mutect2
- ATRNL1 | c.3549G>T p.K1183N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV58090576; called by muse, mutect2, varscan2
- ATRNL1 | c.4127G>A p.G1376E | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100370145, COSV58092217; called by muse, mutect2, varscan2
- ATRX | c.1509A>C p.Q503H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV64881596; called by muse, mutect2, varscan2
- ATXN7L2 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs765299259; called by muse, varscan2
- AURKA | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57168874, COSV57169563; called by muse, mutect2, varscan2
- AURKC | c.625G>T p.E209* (on ENST00000302804 / NM_001015878.2; = p.E175* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as rs1192298496, COSV100248917; called by muse, mutect2, varscan2
- AXDND1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV62640204; called by muse, varscan2
- AXDND1 | c.1230G>A p.K410= | Splice Region (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100858556; called by muse, mutect2, varscan2
- AZIN2 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV53858333; called by muse, mutect2, varscan2
- B4GALT6 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV52702410; called by muse, mutect2, varscan2
- BABAM2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558639513, COSV59622455, COSV59628195; called by muse, mutect2, varscan2
- BACH2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs375103380, COSV57612203; called by muse, mutect2, varscan2
- BAHCC1 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV57026523; called by muse, mutect2, varscan2
- BAIAP2 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs765205664, COSV58363840; called by muse, mutect2, varscan2
- BANK1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs777895274, COSV59842328; called by muse, mutect2, varscan2
- BANK1 | c.1119G>T p.K373N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV59840200; called by muse, mutect2, varscan2
- BAP1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs759024400, COSV56237818, COSV56239121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1A | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1466489502, COSV100701154, COSV62408893; called by muse, mutect2, varscan2
- BBOF1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as rs759037838; called by muse, varscan2
- BBS12 | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs200300023, COSV58562453; called by muse, mutect2, varscan2
- BCAM | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs779640046, COSV99538896; called by mutect2, varscan2
- BCAS1 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65086974; called by muse, mutect2, varscan2
- BCCIP | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV52943402; called by muse, mutect2, varscan2
- BCCIP | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.09); catalogued as rs1401782684, COSV52939292; called by muse, mutect2, varscan2
- BCL2A1 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as rs377180961; called by muse, mutect2, varscan2
- BCL2L13 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs1240706405; called by muse, mutect2, varscan2
- BCL6 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51650775; called by muse, mutect2, varscan2
- BCL7C | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs375059314; called by muse, mutect2, varscan2
- BCORL1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.633); catalogued as COSV54388940; called by muse, mutect2, varscan2
- BCORL1 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139795092; called by muse, mutect2, varscan2
- BDP1 | c.1493-1G>T p.X498_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV62432434; called by muse, varscan2
- BDP1 | c.2791G>T p.E931* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV62433044; called by muse, mutect2, varscan2
- BDP1 | c.3289G>T p.E1097* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV62429815; called by muse, mutect2, varscan2
- BEND2 | c.2218C>A p.L740I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66220990; called by muse, varscan2
- BEND2 | c.1888G>T p.E630* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV66215202; called by muse, mutect2, varscan2
- BEND2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1238581335, COSV101191809; called by muse, varscan2
- BEND4 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); catalogued as COSV101549806; called by muse, varscan2
- BEND5 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs201098567; called by mutect2, varscan2
- BHLHE22 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58861918; called by muse, mutect2, varscan2
- BIK | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 30/96 reads (31%) | catalogued as rs28392636; called by muse, mutect2, varscan2
- BIN1 | c.1243A>C p.I415L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs955442228; called by muse, mutect2, varscan2
- BLK | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV99376815; called by muse, mutect2, varscan2
- BLM | c.1437C>A p.F479L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV61921506, COSV61928073; called by muse, mutect2, varscan2
- BLNK | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782566012, COSV56414279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP5 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs147691986; called by muse, mutect2, varscan2
- BMP5 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63702532, COSV63706127; called by muse, mutect2, varscan2
- BMS1 | c.2764G>A p.V922M | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs547177767; called by muse, mutect2, varscan2
- BMS1 | c.2979C>A p.F993L | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1160411641; called by muse, mutect2, varscan2
- BMX | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100564501; called by muse, mutect2, varscan2
- BNC2 | c.2402T>C p.M801T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as CM152933; called by muse, varscan2
- BNIPL | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs587607488, COSV54845615; called by muse, mutect2, varscan2
- BOD1L1 | c.2561C>A p.S854Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1012513302; called by muse, mutect2, varscan2
- BOLL | c.266T>G p.I89S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99987490; called by muse, mutect2, varscan2
- BPI | c.384C>A p.F128L (on ENST00000262865; = p.F124L on NM_001725.3) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV99480990; called by muse, mutect2, varscan2
- BPIFC | c.144G>T p.K48N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1192764007; called by muse, mutect2, varscan2
- BRAP | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV59537927; called by muse, mutect2, varscan2
- BRCA1 | c.900A>C p.E300D | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs80356861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.4663G>T p.E1555* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV66447920; called by muse, mutect2, varscan2
- BRCA2 | c.4790C>T p.S1597F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.665); catalogued as COSV66451830; called by muse, mutect2, varscan2
- BRCC3 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57461779; called by muse, mutect2, varscan2
- BRD8 | c.3641G>T p.R1214I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV54522732; called by muse, mutect2, varscan2
- BRD9 | c.1147C>A p.L383I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV60244866; called by muse, mutect2, varscan2
- BRDT | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV104423732; called by muse, mutect2, varscan2
- BRDT | c.1755G>T p.K585N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV62865536; called by muse, mutect2, varscan2
- BRINP1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.151); catalogued as rs763882375, COSV56292953; called by mutect2, varscan2
- BRINP3 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs1369646899, COSV66517169; called by muse, mutect2, varscan2
- BRIX1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1175030766; called by muse, mutect2, varscan2
- BRPF1 | c.1983+7G>A | Splice Region (SNP) | VAF 21/47 reads (45%) | catalogued as rs751452778; called by muse, mutect2, varscan2
- BRWD3 | c.4627C>T p.R1543W | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs755270226, COSV64745068; called by muse, mutect2, varscan2
- BRWD3 | c.3373G>T p.E1125* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100955559; called by muse, mutect2, varscan2
- BSCL2 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54016850; called by muse, mutect2, varscan2
- BTAF1 | c.2616G>T p.E872D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56431340; called by muse, mutect2, varscan2
- BTBD11 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs765978569, COSV55021439; called by muse, mutect2, varscan2
- BTBD11 | c.2090C>A p.A697D (on ENST00000280758 / NM_001018072.2; = p.A234D on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55027308; called by muse, mutect2, varscan2
- BTBD6 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272881375, COSV59268541; called by muse, mutect2
- BTBD9 | c.132G>T p.K44N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.239); catalogued as rs1419185468, COSV58430808; called by muse, mutect2, varscan2
- BTD | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as CM033344, CM993545; called by muse, varscan2
- BTK | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58121149; called by muse, varscan2
- BTN3A2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs764723723, COSV62687870; called by muse, mutect2, varscan2
- BTNL2 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66630193; called by muse, varscan2
- BUB1 | c.2556C>A p.F852L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV100241346; called by muse, mutect2, varscan2
- BUB1 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV57061159; called by muse, mutect2, varscan2
- BUB1 | c.224T>G p.F75C | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV57063401; called by muse, mutect2, varscan2
- BUB1 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.798); catalogued as rs1801328; called by muse, mutect2, varscan2
- C10orf120 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1431253930, COSV61491778, COSV61492642; called by muse, mutect2, varscan2
- C11orf87 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100535879; called by muse, mutect2, varscan2
- C12orf4 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1050781287; called by muse, mutect2, varscan2
- C12orf4 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs532268400, COSV54205508; called by muse, mutect2, varscan2
- C18orf54 | c.26G>T p.R9I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs780701874; called by muse, mutect2, varscan2
- C1QTNF1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546733985, COSV59261657; called by mutect2, varscan2
- C1QTNF2 | c.311G>A p.R104Q (on ENST00000393975; = p.R59Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs759937511, COSV67432358; called by muse, mutect2, varscan2
- C1QTNF5 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as rs750204794; called by muse, mutect2, varscan2
- C1R | c.955G>A p.E319K (on ENST00000536053 / NM_001354346.2; = p.E305K on NM_001733.7) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as rs767341899, COSV73293822; called by muse, mutect2, varscan2
- C1RL | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56923600; called by muse, mutect2, varscan2
- C1S | c.840A>C p.K280N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781896129; called by muse, mutect2, varscan2
- C1orf105 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as COSV62959188; called by mutect2, varscan2
- C1orf116 | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs781554923; called by muse, mutect2, varscan2
- C1orf131 | c.863C>A p.S288Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59642423; called by muse, mutect2, varscan2
- C1orf141 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV63993469; called by muse, varscan2
- C1orf141 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV63992007; called by muse, varscan2
- C1orf210 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as rs1268460954; called by muse, mutect2, varscan2
- C1orf87 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.178); catalogued as COSV100967009; called by muse, mutect2, varscan2
- C1orf94 | c.1209G>T p.K403N (on ENST00000488417 / NM_001134734.2; = p.K213N on NM_032884.5) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64914997, COSV64915624; called by muse, mutect2, varscan2
- C20orf96 | c.234G>T p.K78N (on ENST00000360321 / NM_153269.3; = p.K77N on NM_080571.1) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV100826705, COSV64403470; called by muse, mutect2, varscan2
- C22orf31 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs1248701859; called by mutect2, varscan2
- C2CD3 | c.2864C>A p.S955Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1482717429; called by muse, mutect2, varscan2
- C2CD6 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.773); catalogued as COSV53795129; called by muse, mutect2, varscan2
- C2orf42 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs773883102, COSV52450123; called by muse, mutect2, varscan2
- C2orf80 | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs756574519, COSV58017729; called by mutect2, varscan2
- C3 | c.4828G>A p.D1610N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1204648676; called by muse, varscan2
- C3 | c.720G>T p.E240D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV55568749; called by muse, mutect2, varscan2
- C3AR1 | c.586T>A p.S196T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1359919865; called by muse, varscan2
- C3orf20 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99514206, COSV99514310; called by muse, varscan2
- C4A | c.2787G>T p.K929N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562724722; called by muse, varscan2
- C4orf51 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV71263879; called by muse, mutect2, varscan2
- C5orf38 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs772380035, COSV100121673, COSV57412756, COSV57414154; called by muse, varscan2
- C5orf46 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV59154497; called by muse, mutect2, varscan2
- C6orf118 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.887); catalogued as rs201539458, COSV57815326; called by muse, mutect2, varscan2
- C7orf25 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752752618; called by muse, mutect2, varscan2
- C7orf31 | c.1740C>A p.F580L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as COSV99384146, COSV99384164; called by muse, mutect2, varscan2
- C7orf57 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV62362409; called by muse, mutect2, varscan2
- C8orf34 | c.332T>G p.L111* | Nonsense Mutation (SNP) | VAF 45/90 reads (50%) | catalogued as COSV100444779; called by muse, mutect2, varscan2
- C8orf34 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1461696168, COSV100298747; called by muse, mutect2, varscan2
- C8orf76 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs754108694; called by muse, mutect2, varscan2
- C9 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as COSV54681827; called by muse, mutect2, varscan2
- C9orf43 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99928559; called by muse, mutect2, varscan2
- CA10 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200396465, COSV99562138; called by muse, mutect2, varscan2
- CA11 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs766042493; called by muse, mutect2, varscan2
- CA5B | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs763906499; called by muse, mutect2, varscan2
- CABIN1 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1367466542; called by muse, mutect2, varscan2
- CABLES1 | c.1793G>A p.R598Q (on ENST00000256925 / NM_001100619.2; = p.R333Q on NM_138375.2) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs759309191, COSV99908911; called by muse, mutect2, varscan2
- CABP1 | c.712G>A p.D238N (on ENST00000316803 / NM_001033677.1; = p.D35N on NM_004276.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56457967, COSV56458311; called by muse, mutect2, varscan2
- CABS1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56734419; called by muse, mutect2, varscan2
- CABYR | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs1442573976; called by muse, varscan2
- CACHD1 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs146843239; called by muse, mutect2, varscan2
- CACNA1A | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64202274; called by muse, mutect2, varscan2
- CACNA1B | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771121255; called by muse, mutect2, varscan2
- CACNA1C | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs755167125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.1520T>C p.L507P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1317857450; called by muse, mutect2, varscan2
- CACNA1E | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs763922481; called by muse, mutect2, varscan2
- CACNA1E | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs926850053; called by muse, mutect2, varscan2
- CACNA1E | c.3357G>T p.E1119D | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100701320; called by muse, mutect2, varscan2
- CACNA1H | c.4010C>T p.A1337V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.739); catalogued as rs1407322465; called by muse, mutect2, varscan2
- CACNA1S | c.4573G>A p.A1525T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs760097708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D1 | c.1723C>T p.R575* (on ENST00000356253 / NM_001366867.1; = p.R556* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as rs730880057, COSV62374963; called by mutect2, varscan2
- CACNA2D3 | c.2626G>T p.D876Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV55560133; called by muse, mutect2, varscan2
- CACNB2 | c.1027G>T p.E343* (on ENST00000324631 / NM_201596.3; = p.E288* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs1554838959, COSV104389537; called by muse, mutect2, varscan2
- CACNB2 | c.1918G>T p.E640* (on ENST00000324631 / NM_201596.3; = p.E585* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as rs774309277; called by muse, mutect2, varscan2
- CACNG1 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs144718253; called by muse, mutect2, varscan2
- CADM4 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs890982613, COSV55928349; called by muse, mutect2, varscan2
- CADPS2 | c.3736C>T p.R1246* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs1354028382, COSV57349948, COSV57350326; called by muse, mutect2, varscan2
- CALCOCO1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100017230; called by muse, mutect2, varscan2
- CALCRL | c.1375T>G p.L459V | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as rs764560081; called by muse, mutect2, varscan2
- CALCRL | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as COSV101131029; called by muse, varscan2
- CALD1 | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.812); catalogued as COSV62646688, COSV62647554; called by muse, mutect2, varscan2
- CALHM5 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.357); catalogued as rs1409887888, COSV100635646; called by muse, mutect2, varscan2
- CAMK1D | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762036652; called by muse, mutect2, varscan2
- CAMK2D | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56437111, COSV99594431; called by muse, mutect2, varscan2
- CAMKMT | c.437+1G>T p.X146_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | catalogued as rs1234595374; called by muse, mutect2, varscan2
- CAMKMT | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.761); catalogued as rs201075899, COSV65923575; called by muse, mutect2, varscan2
- CAMSAP1 | c.4685G>A p.R1562Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764759860, COSV56721299; called by muse, mutect2, varscan2
- CAMSAP1 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1265391740, COSV56719110; called by muse, mutect2, varscan2
- CAMSAP3 | c.3434G>A p.R1145H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs753692728, COSV50341450; called by muse, varscan2
- CAMTA1 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1417768010, COSV57884358; called by muse, mutect2, varscan2
- CAMTA1 | c.1848C>A p.F616L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.45); PolyPhen probably damaging (0.952); catalogued as COSV57926986; called by muse, varscan2
- CAND1 | c.2080C>A p.L694I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV73389821; called by muse, mutect2, varscan2
- CAPN3 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM080115, COSV58823544; called by muse, mutect2, varscan2
- CAPN3 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 47/108 reads (44%) | catalogued as CM990305, COSV58820875; called by muse, mutect2, varscan2
- CAPS2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780956187, COSV60823981; called by muse, mutect2, varscan2
- CAPSL | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs199837654; called by muse, mutect2, varscan2
- CARMIL3 | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.622); catalogued as COSV57725257; called by muse, mutect2, varscan2
- CARS2 | c.1400C>A p.S467Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1456089145, COSV57284144; called by muse, mutect2, varscan2
- CASD1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV51974004; called by muse, mutect2, varscan2
- CASD1 | c.1098A>G p.I366M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs745942988, COSV51973700; called by mutect2, varscan2
- CASK | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs868537608, COSV59374892; called by muse, mutect2, varscan2
- CASK | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.279); catalogued as COSV59368059; called by muse, mutect2, varscan2
- CASK | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59366002; called by muse, mutect2, varscan2
- CASP3 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as rs1037653105, COSV57724864; called by muse, varscan2
- CASP4 | c.845C>A p.S282* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV101274082; called by muse, mutect2, varscan2
- CASP8 | c.412-1G>T p.X138_splice (on ENST00000432109 / NM_033355.3; = p.X170_splice on NM_001228.4) | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV51845122, COSV51859458; called by muse, mutect2, varscan2
- CASQ1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368579149; called by muse, varscan2
- CASR | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.434); catalogued as rs1559959206, COSV56139690; called by muse, mutect2, varscan2
- CASR | c.2090G>A p.G697D (on ENST00000490131; = p.G774D on NM_000388.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV99948806; called by muse, mutect2, varscan2
- CASZ1 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs751784290; called by muse, mutect2, varscan2
- CATSPER1 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs143644621; called by muse, mutect2, varscan2
- CATSPERE | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63678721, COSV63679946; called by muse, varscan2
- CAVIN2 | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58425929; called by muse, mutect2, varscan2
- CAVIN4 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as rs374741826; called by muse, varscan2
- CBL | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50645894; called by muse, mutect2, varscan2
- CBLL2 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV100081670; called by mutect2, varscan2
- CC2D2B | c.468C>A p.F156L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV60358626, COSV60359506; called by mutect2, varscan2
- CCDC102B | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs186843401, COSV60140682; called by muse, mutect2, varscan2
- CCDC110 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs777082668, COSV104409873; called by muse, mutect2, varscan2
- CCDC110 | c.1385T>G p.L462R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56873442; called by mutect2, varscan2
- CCDC112 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1561493321; called by muse, mutect2, varscan2
- CCDC136 | c.2381C>T p.T794I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as rs769101580; called by mutect2, varscan2
- CCDC14 | c.1105C>T p.R369* (on ENST00000488653; = p.R321* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as rs200601158, COSV59943859; called by muse, mutect2, varscan2
- CCDC144A | c.2345G>T p.R782I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV60700702; called by muse, mutect2, varscan2
- CCDC146 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs552375827, COSV53544047, COSV99035595; called by muse, mutect2, varscan2
- CCDC146 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.198); catalogued as rs1192974559, COSV53544201, COSV53548881; called by muse, mutect2, varscan2
- CCDC146 | c.2670C>A p.F890L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV53550372; called by muse, mutect2, varscan2
- CCDC150 | c.1610C>A p.S537Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV55871536; called by muse, mutect2, varscan2
- CCDC158 | c.3327A>C p.K1109N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs746529199; called by muse, mutect2, varscan2
- CCDC158 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV66355899; called by muse, mutect2, varscan2
- CCDC170 | c.1916C>A p.S639Y | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV53340031; called by muse, varscan2
- CCDC171 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs906479020; called by muse, mutect2, varscan2
- CCDC18 | c.3673C>T p.H1225Y (on ENST00000343253 / NM_001306076.1; = p.H1226Y on NM_206886.4) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV58145922; called by muse, mutect2, varscan2
- CCDC181 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV63157946; called by muse, mutect2, varscan2
- CCDC186 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as rs778744440; called by muse, mutect2, varscan2
- CCDC190 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV63362841; called by muse, mutect2, varscan2
- CCDC27 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs765862740; called by muse, mutect2, varscan2
- CCDC39 | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV99868193; called by muse, mutect2, varscan2
- CCDC42 | c.157A>T p.I53F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.139); catalogued as rs770960822; called by muse, mutect2, varscan2
- CCDC63 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.112); catalogued as rs771937207, COSV57528506, COSV57531266; called by muse, mutect2, varscan2
- CCDC68 | c.830G>T p.R277I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs1322562293, COSV61603833; called by muse, varscan2
- CCDC69 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV104415402, COSV62600274; called by muse, varscan2
- CCDC7 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289601737; called by muse, mutect2, varscan2
- CCDC7 | c.2864C>A p.S955Y | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1342491423; called by muse, mutect2
- CCDC80 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV52817590; called by muse, mutect2, varscan2
- CCDC87 | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs759355395, COSV59579158; called by mutect2, varscan2
- CCDC88A | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV55056392; called by muse, mutect2, varscan2
- CCDC88C | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs979239156, COSV66235085; called by muse, mutect2, varscan2
- CCDC96 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368331948; called by muse, mutect2, varscan2
- CCKAR | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs745998238, COSV55163967; called by muse, mutect2, varscan2
- CCN4 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs763794115; called by muse, varscan2
- CCNB3 | c.972G>T p.E324D | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as rs3810683; called by muse, mutect2, varscan2
- CCNB3 | c.1602G>T p.K534N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); catalogued as COSV52070039, COSV99329356; called by muse, mutect2, varscan2
- CCNF | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs369725393; called by mutect2, varscan2
- CCNJL | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV57445285; called by muse, mutect2, varscan2
- CCNT1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV56065445; called by muse, mutect2, varscan2
- CCNT2 | c.960T>G p.I320M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.051); catalogued as rs1241661507; called by muse, mutect2
- CCNYL1 | c.586C>T p.R196C (on ENST00000295414 / NM_001330218.2; = p.R126C on NM_152523.2) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs1217839974, COSV54942097; called by muse, mutect2, varscan2
- CCR1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV56122989; called by muse, mutect2, varscan2
- CCR2 | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.06); catalogued as rs1166098549, COSV52748313; called by muse, mutect2, varscan2
- CCR5 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs781713216, COSV52751000, COSV52751098; called by muse, varscan2
- CCSER1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1362443481, COSV61452464; called by muse, mutect2, varscan2
- CCT6B | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs755333614, COSV58487981; called by muse, mutect2, varscan2
- CCT6B | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58488189; called by muse, mutect2, varscan2
- CD163L1 | c.3964C>A p.L1322I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58020456; called by muse, mutect2, varscan2
- CD164L2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs138011471; called by muse, mutect2, varscan2
- CD19 | c.968G>T p.R323I | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61188162; called by muse, mutect2, varscan2
- CD1A | c.564G>T p.L188F | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV99192138; called by muse, varscan2
- CD1A | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778580983; called by muse, mutect2, varscan2
- CD1B | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.041); catalogued as rs747870947; called by muse, varscan2
- CD1B | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63805065; called by muse, varscan2
- CD209 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV52659763; called by muse, mutect2, varscan2
- CD244 | c.688T>A p.F230I (on ENST00000368033 / NM_001166663.2; = p.F225I on NM_016382.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV59238344; called by muse, mutect2, varscan2
- CD247 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV62978519; called by muse, mutect2, varscan2
- CD2AP | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV63759282; called by muse, mutect2, varscan2
- CD36 | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs763513155; called by muse, varscan2
- CD36 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs766072001, COSV59217553; called by muse, mutect2, varscan2
- CD40LG | c.412T>G p.L138V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD930917; called by muse, mutect2, varscan2
- CD44 | c.2202G>T p.Q734H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV53530156; called by muse, mutect2, varscan2
- CD46 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as COSV59733188; called by muse, mutect2, varscan2
- CD55 | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.729); catalogued as rs780622604, COSV100132497; called by muse, mutect2, varscan2
- CD70 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1166621473, COSV99835476; called by muse, mutect2, varscan2
- CD93 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1176351050, COSV55663540; called by muse, mutect2, varscan2
- CDADC1 | c.1410+2T>C p.X470_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as rs778329903; called by muse, mutect2, varscan2
- CDC23 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as rs1273411313; called by muse, mutect2, varscan2
- CDC27 | c.2280C>A p.F760L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV50698071; called by muse, mutect2, varscan2
- CDC42BPA | c.4498C>A p.L1500I (on ENST00000334218 / NM_001366019.2; = p.L1487I on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62015813; called by muse, mutect2, varscan2
- CDC5L | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV65175963; called by muse, mutect2, varscan2
- CDC5L | c.1890A>C p.K630N | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV65175703; called by muse, mutect2, varscan2
- CDCA7L | c.218T>G p.F73C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62259127; called by muse, mutect2, varscan2
- CDH10 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV100051544, COSV52581723; called by muse, mutect2
- CDH10 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs754465931, COSV52569054, COSV52590251; called by muse, mutect2, varscan2
- CDH12 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66388805, COSV66392944; called by muse, mutect2, varscan2
- CDH16 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs777915267; called by mutect2, varscan2
- CDH18 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56939072; called by muse, varscan2
- CDH2 | c.2011C>A p.L671I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52273005, COSV52288135; called by mutect2, varscan2
- CDH23 | c.5018C>T p.A1673V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as rs558052046; called by muse, mutect2, varscan2
- CDH6 | c.2045C>A p.A682D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV99421013; called by muse, mutect2, varscan2
- CDH7 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); catalogued as rs745446929, COSV100542520; called by muse, mutect2, varscan2
- CDH8 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV100184438, COSV54861232; called by muse, mutect2, varscan2
- CDHR5 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV51564015; called by muse, mutect2, varscan2
- CDK11A | c.376C>T p.R126* (on ENST00000378633 / NM_001313896.2; = p.R136* on NM_024011.4) | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs1240371604; called by muse, mutect2, varscan2
- CDK13 | c.2493G>T p.K831N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV51702721; called by muse, mutect2, varscan2
- CDK15 | c.249G>T p.E83D (on ENST00000652192 / NM_001366386.2; = p.E32D on NM_139158.2) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV53632024; called by muse, varscan2
- CDK15 | c.443G>A p.R148Q (on ENST00000652192 / NM_001366386.2; = p.R97Q on NM_139158.2) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370446004; called by muse, mutect2, varscan2
- CDK5RAP2 | c.488G>T p.R163I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62572945, COSV62573650; called by muse, mutect2, varscan2
- CDK7 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56512884; called by muse, mutect2, varscan2
- CDKL2 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs750133894, COSV56733991; called by muse, mutect2, varscan2
- CDKL4 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as COSV101115214; called by muse, mutect2
- CDNF | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as rs1168824330, COSV65805700, COSV65805971, COSV65806275; called by mutect2, varscan2
- CDR1 | c.632G>T p.R211I | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV65164495; called by muse, mutect2, varscan2
- CDT1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs771416695; called by muse, varscan2
- CDYL | c.944T>G p.F315C (on ENST00000328908 / NM_001368125.1; = p.F261C on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV100189952; called by muse, mutect2, varscan2
- CDYL2 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV73653975; called by muse, mutect2, varscan2
- CEACAM20 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs781770394, COSV57602047; called by muse, varscan2
- CEACAM20 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as rs1158227065; called by muse, mutect2, varscan2
- CEACAM21 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99494648; called by mutect2, varscan2
- CEACAM4 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV55732473, COSV55733056; called by muse, mutect2, varscan2
- CECR2 | c.2372C>A p.S791Y (on ENST00000342247 / NM_001290047.2; = p.S608Y on NM_001290046.1) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV52838349; called by muse, mutect2, varscan2
- CELA1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs376966959; called by muse, mutect2, varscan2
- CELA3A | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs865944700, COSV99266797; called by muse, mutect2, varscan2
- CELSR2 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54779295; called by muse, mutect2, varscan2
- CENPE | c.6906C>A p.F2302L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV54377640; called by muse, mutect2, varscan2
- CENPF | c.1818G>T p.K606N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs766583888; called by muse, varscan2
- CENPF | c.5346G>T p.E1782D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs372338929; called by muse, mutect2, varscan2
- CENPH | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs200925138; called by muse, mutect2, varscan2
- CENPN | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs528102999, COSV55141477; called by muse, mutect2, varscan2
- CEP152 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1453843365, COSV57861618; called by muse, mutect2, varscan2
- CEP162 | c.2891T>G p.F964C | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560930481; called by muse, mutect2, varscan2
- CEP164 | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV54039545; called by muse, mutect2, varscan2
- CEP192 | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as rs769070576; called by muse, mutect2, varscan2
- CEP192 | c.7400C>A p.S2467Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1169473037, COSV58062657; called by muse, mutect2, varscan2
- CEP290 | c.3858C>A p.F1286L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1353300022, COSV58355928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP290 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs562747993, COSV58352144; called by muse, mutect2, varscan2
- CEP350 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs372724544; called by muse, mutect2, varscan2
- CEP350 | c.4873C>T p.R1625* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as rs1181129362, COSV62601953; called by muse, mutect2, varscan2
- CEP63 | c.1417A>C p.N473H | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59675303; called by muse, mutect2, varscan2
- CEP70 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as rs1301844065; called by muse, mutect2, varscan2
- CERKL | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.066); catalogued as rs775435174, COSV59207159; called by muse, mutect2, varscan2
- CERS5 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs763130138; called by muse, mutect2, varscan2
- CES4A | c.1661G>T p.R554I (on ENST00000648724 / NM_001364782.1; = p.R456I on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100110241; called by muse, mutect2, varscan2
- CFAP206 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405987812, COSV65806689; called by muse, mutect2, varscan2
- CFAP221 | c.949T>G p.L317V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as rs753441574; called by muse, mutect2, varscan2
- CFAP221 | c.1770C>A p.F590L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1458617828; called by muse, mutect2, varscan2
- CFAP221 | c.2515C>A p.L839I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs775946355; called by muse, mutect2, varscan2
- CFAP36 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs763494988, COSV59117634; called by muse, mutect2, varscan2
- CFAP43 | c.3505A>C p.K1169Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); catalogued as rs192966094; called by muse, varscan2
- CFAP43 | c.3487G>T p.D1163Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV63853070, COSV63854959; called by muse, varscan2
- CFAP43 | c.3007G>T p.E1003* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV53378639; called by muse, mutect2, varscan2
- CFAP43 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs747096752, COSV53376033; called by muse, mutect2, varscan2
- CFAP47 | c.5228A>G p.N1743S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100545029; called by muse, mutect2, varscan2
- CFAP52 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1241233475; called by muse, mutect2, varscan2
- CFAP53 | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as rs769530411; called by muse, mutect2
- CFAP57 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV65265096; called by muse, varscan2
- CFAP58 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as rs1467834668; called by muse, mutect2, varscan2
- CFAP61 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs61744710; called by muse, mutect2, varscan2
- CFAP65 | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs756973049, COSV58568377; called by muse, mutect2, varscan2
- CFAP65 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs781313239, COSV100444641; called by muse, mutect2, varscan2
- CFAP65 | c.361G>A p.A121T (on ENST00000341552 / NM_194302.4; = p.A56T on NM_152389.4) | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs752571190, COSV55389204; called by muse, mutect2, varscan2
- CFAP69 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100289788, COSV100290447; called by muse, varscan2
- CFAP92 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV54046919; called by muse, mutect2, varscan2
- CFHR2 | c.638T>G p.I213S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV66381302; called by muse, mutect2, varscan2
- CGAS | c.1295A>C p.K432T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV104427450; called by muse, varscan2
- CHD4 | c.3974G>T p.R1325I (on ENST00000357008 / NM_001363606.2; = p.R1338I on NM_001273.5) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58895972, COSV58909317; called by muse, mutect2, varscan2
- CHD7 | c.2545G>T p.D849Y | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs775998353, COSV71112121; called by muse, mutect2, varscan2
- CHEK2 | c.1021T>G p.Y341D (on ENST00000382580 / NM_001005735.2; = p.Y298D on NM_007194.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs878854927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHI3L2 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1039610150, COSV63874430; called by muse, mutect2, varscan2
10,996 further variants in this file (8,640 protein-altering or splice-affecting, 2,057 silent, 299 other) are not listed here.
